Somatic mutation profile of tumor specimen TARGET-15-SJMPAL042794-09A.1 (aliquot TARGET-15-SJMPAL042794-09A.1-01D) from TARGET case TARGET-15-SJMPAL042794, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.2 years (5,541 days).
Specimen TARGET-15-SJMPAL042794-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1cba7e5-9a53-40f7-b4e9-671954ac9de9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL042794-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL042794-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/812612ca-0369-4a91-9447-9c28c1d7029a

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Nonsense Mutation 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA2 | c.958G>T p.G320C | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559986079; called by muse, mutect2, varscan2
- TCF25 | c.1361C>A p.A454E | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54531106; called by muse, mutect2
- CXCR6 | c.765C>A p.S255R | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.045); called by muse, mutect2
- DOK4 | c.776G>T p.C259F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.269); called by muse, mutect2
- JMJD1C | c.5302G>T p.V1768F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- LRRC7 | c.2803C>A p.H935N (on ENST00000651989 / NM_001370785.2; = p.H902N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); called by mutect2, varscan2
- TRIM46 | c.2049C>A p.C683* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2, varscan2
- ATXN2 | c.528G>A p.Q176= (on ENST00000550104; = p.Q16= on NM_002973.4) | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs1180787672; called by muse, varscan2
- CCDC68 | c.-8-40G>T | Intron (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
